Somatic mutation profile of tumor specimen TARGET-20-PANGTF-04A (aliquot TARGET-20-PANGTF-04A-01D) from TARGET case TARGET-20-PANGTF, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.9 years (5,814 days).
Specimen TARGET-20-PANGTF-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6021d1e1-af33-4fca-838b-cffe5a8ac2cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANGTF-14A (Bone Marrow Normal), aliquot TARGET-20-PANGTF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66d43982-5d14-4a4a-8bc1-e45b77a1dc9f

The open-access MAF lists 14 somatic variants for this specimen: 7 protein-altering or splice-affecting, 7 silent.
By variant classification: Silent 7, Missense Mutation 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.1772C>G p.T591R | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV60712420; called by muse, mutect2
- GEN1 | c.965G>A p.C322Y | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV58058565; called by muse, mutect2, varscan2
- LCE1F | c.311G>C p.S104T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.158); catalogued as COSV57669629, COSV57669714; called by muse, mutect2, varscan2
- SPAG9 | c.2800G>A p.V934M (on ENST00000262013 / NM_001130528.3; = p.V920M on NM_003971.6) | Missense Mutation (SNP) | VAF 37/218 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as COSV56243988; called by muse, mutect2, varscan2
- TBC1D8B | c.1475T>G p.L492* | Nonsense Mutation (SNP) | VAF 60/354 reads (17%) | catalogued as COSV52179472; called by muse, mutect2, varscan2
- THADA | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1257223390, COSV57689540; called by muse, mutect2, varscan2
- XDH | c.1985C>T p.T662I | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.88); catalogued as rs374486058; called by muse, mutect2, varscan2
- AASS | c.102C>T p.N34= | Silent (SNP) | VAF 16/157 reads (10%) | catalogued as rs777413121, COSV62788601, COSV62790808; called by muse, mutect2, varscan2
- ANXA2 | c.361C>T p.L121= | Silent (SNP) | VAF 25/193 reads (13%) | catalogued as COSV60317656; called by muse, mutect2, varscan2
- COL4A3 | c.1887G>A p.T629= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs201109911; called by mutect2, varscan2
- DOP1B | c.3351C>T p.S1117= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs569439616; called by muse, mutect2
- HS6ST2 | c.906C>T p.S302= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV63710388; called by muse, mutect2
- PXN | c.1245G>A p.P415= (on ENST00000228307 / NM_001080855.3; = p.P381= on NM_002859.4) | Silent (SNP) | VAF 41/247 reads (17%) | catalogued as rs758460029, COSV57217528; called by muse, mutect2, varscan2
- SOS1 | c.3642A>G p.L1214= | Silent (SNP) | VAF 21/171 reads (12%) | catalogued as COSV67676414; called by muse, mutect2, varscan2
